TCGA case TCGA-ZJ-AB0I — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: NCI HRE Branch. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a4f13656-a941-498a-9ac9-f020ed559b35

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 25 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 26.0 years (9,486 days); Year of diagnosis: 2006; Method of diagnosis: Biopsy; AJCC pathologic T: T2b; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IIB; FIGO staging edition year: 1995; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 0 days.
   Pathology details: Consistent pathology review: Yes.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 0.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Weight: 78 kg; Height: 173 cm; BMI: 26.1.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 13; Tobacco smoking quit year: 2006; Age at onset: 13.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZJ-AB0I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 200 mg.
  Slide TCGA-ZJ-AB0I-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ZJ-AB0I-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZJ-AB0I-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Live birth pregnancy count: 4; Total pregnancy count: 4; Tobacco smoking history indicator: 4; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 0 days; disease-specific survival: no event (censored), 0 days; progression-free interval: no event (censored), 0 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZJ-AB0I-01A-11D-A42N-01): tumor purity 0.9, ploidy 2.14, whole-genome doublings 0.
